TCGA case TCGA-AA-A010 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0712566e-3371-4715-95f1-5b792e72d758

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.4; Tissue or organ of origin: Transverse colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 46.3 years (16,922 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,064 days (2.9 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 45; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 0 days; Days to treatment end: 183 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 1,064 days (2.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 0.2 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-A010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 700 mg.
  Slide TCGA-AA-A010-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 24; Percent lymphocyte infiltration: 17; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A010-01A-01-MS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 28; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-AA-A010-01A-06-BS6: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 35; Percent normal cells: 30; Percent necrosis: 2; Percent stromal cells: 8; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 4.
  Slide TCGA-AA-A010-01A-06-TS6: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 7; Percent necrosis: 2; Percent stromal cells: 11; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
  Slide TCGA-AA-A010-01A-04-BS4: Section location: Bottom; Percent tumor cells: 61; Percent tumor nuclei: 55; Percent normal cells: 30; Percent necrosis: 1; Percent stromal cells: 8; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A010-01A-04-TS4: Section location: Top; Percent tumor cells: 59; Percent tumor nuclei: 55; Percent normal cells: 30; Percent necrosis: 1; Percent stromal cells: 10; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A010-01A-01-BS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A010-01A-02-BS2: Section location: Bottom; Percent tumor cells: 66; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 33; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
  Slide TCGA-AA-A010-01A-05-BS5: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 12; Percent necrosis: 2; Percent stromal cells: 11; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-AA-A010-01A-05-TS5: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 7; Percent necrosis: 2; Percent stromal cells: 11; Percent lymphocyte infiltration: 13; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-AA-A010-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-A010-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 0.20; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Folinic acid.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,064 days; disease-specific survival: no event (censored), 1,064 days; disease-free interval: no event (censored), 1,064 days; progression-free interval: no event (censored), 1,064 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-A010-01A-01D-A008-01): tumor purity 0.77, ploidy 2.01, whole-genome doublings 0.
